Gene-level copy-number profile of tumor specimen C3N-03486-03 from CPTAC case C3N-03486, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 65.3 years (23,849 days).
Specimen C3N-03486-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d68c03cd-d171-4f5d-978d-9a41c4b8bd55.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03486-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/6bcb461e-5f83-435e-b48c-8f1114b4671c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 514; copy number 1: 5; copy number 2: 14,499; copy number 3: 2,940; copy number 4: 33,116; copy number 5: 513; copy number 6: 5,308; copy number 7: 17; copy number 8: 1,206; copy number 9: 77; copy number 10: 242; copy number 11: 2; copy number 12: 271; copy number 14: 27; copy number 15: 121; copy number 43: 6; copy number 51: 44.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,607,184–11,612,197, 2 genes (within-gene range 0–2): AC022001.2, AC022001.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 790 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:155,760,617–185,052,614, 447 genes, copy number 9–15 (broad region; genes not listed).
- chr5:180,967,189–181,006,727, 4 genes, copy number 10: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr11:68,683,779–80,957,634, 337 genes, copy number 9–51 (broad region; genes not listed).
- chr18:30,713,275–30,780,424, 2 genes, copy number 11: AC090506.1, AC090506.2.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
